Somatic mutation profile of tumor specimen C3N-01023-04 (aliquot CPT0105060009) from CPTAC case C3N-01023, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.2 years (21,265 days).
Specimen C3N-01023-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46b2dee1-8d31-475a-8ca1-2e27250c3a86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01023-31 (Blood Derived Normal), aliquot CPT0107620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ee3e3c-0535-4214-beb7-3ced17b6508a

The open-access MAF lists 229 somatic variants for this specimen: 155 protein-altering or splice-affecting, 45 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 45, Nonsense Mutation 11, Intron 11, RNA 9, Splice Site 3, Splice Region 3, 5'UTR 3, 3'UTR 3, Frame Shift Del 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 89/348 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA9 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV60623390; called by muse, mutect2
- AKR1D1 | c.836G>T p.R279M | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV54337827; called by muse, mutect2
- ANKRD30A | c.3670C>T p.H1224Y (on ENST00000611781; = p.H1168Y on NM_052997.2) | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64605247; called by muse, mutect2, varscan2
- ATM | c.6313A>T p.R2105W | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879253983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GAT1 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV56998602; called by muse, mutect2
- BRAF | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56185391, COSV99962917; called by muse, mutect2, varscan2
- CBLN1 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 49/349 reads (14%) | catalogued as COSV99535741; called by muse, mutect2, varscan2
- CCDC141 | c.3733C>G p.H1245D | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV55371028; called by muse, mutect2
- CDH20 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 129/551 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53013378; called by muse, mutect2, varscan2
- CDH7 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 25/176 reads (14%) | catalogued as rs1454134664, COSV59896090; called by muse, mutect2, varscan2
- CNTNAP4 | c.3807G>T p.R1269S | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs372665319, COSV56674039, COSV56678806, COSV56686594; called by muse, mutect2, varscan2
- COL5A1 | c.5311G>A p.D1771N | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1005244744; ClinVar: uncertain significance; called by muse, mutect2
- CRACD | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99949024; called by muse, mutect2, varscan2
- DHX9 | c.3598G>T p.G1200C | Missense Mutation (SNP) | VAF 235/611 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62362897; called by muse, mutect2, varscan2
- ELANE | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM078497; called by muse, mutect2, varscan2
- ESPNL | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs865881007, COSV100547721; called by muse, mutect2, varscan2
- FREM1 | c.88C>A p.R30S | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV66522250, COSV66523713; called by muse, mutect2, varscan2
- HDAC9 | c.1762C>A p.R588S | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV67765772; called by muse, mutect2, varscan2
- KHDC1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV57614526, COSV57616506; called by muse, mutect2, varscan2
- KLHDC1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 32/316 reads (10%) | catalogued as COSV100833624; called by muse, mutect2
- LNPEP | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375167356, COSV51481719; called by muse, mutect2
- LRFN1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750828066; called by muse, mutect2
- MARCHF6 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99929644; called by muse, mutect2, varscan2
- MROH8 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs551443709, COSV54119925; called by muse, mutect2, varscan2
- MTUS2 | c.2608G>T p.D870Y | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1457491588; called by muse, mutect2, varscan2
- MUC16 | c.28594C>A p.L9532I | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.042); catalogued as rs770958840; called by muse, mutect2, varscan2
- MUC2 | c.2279C>A p.T760K | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs766355002; called by muse, mutect2, varscan2
- MYH8 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1448637732; called by muse, mutect2
- NLRC5 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1428109693, COSV99346286; called by muse, mutect2, varscan2
- OIT3 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs374979283; called by muse, mutect2, varscan2
- OR13D1 | c.588G>C p.M196I | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV59513948; called by muse, mutect2, varscan2
- POLK | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1344678997; called by muse, mutect2, varscan2
- POM121L12 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.633); catalogued as COSV68693368; called by muse, mutect2, varscan2
- PPFIA2 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs929306228; called by muse, mutect2, varscan2
- PRSS22 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 96/358 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50721670; called by muse, mutect2, varscan2
- PTPRO | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99839964; called by muse, mutect2, varscan2
- PTPRT | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.506); catalogued as COSV61973275; called by muse, varscan2
- RAB37 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs766791134; called by muse, mutect2
- RFX6 | c.2261C>A p.P754Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.416); catalogued as COSV60587389; called by muse, mutect2, varscan2
- RGS7 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 51/471 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1408037935; called by muse, mutect2, varscan2
- RTL4 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs745929651, COSV61207204; called by muse, mutect2, varscan2
- SCART1 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs899954621, COSV62986148; called by muse, mutect2
- SLITRK1 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs760077886, COSV65678429; called by muse, mutect2, varscan2
- SLITRK2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs782518844, COSV59429934; called by muse, mutect2, varscan2
- SLITRK4 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV62023314; called by muse, mutect2, varscan2
- SORCS3 | c.2827G>T p.G943W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63796655; called by muse, mutect2, varscan2
- SPATA17 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776432950; called by muse, mutect2, varscan2
- SPTA1 | c.4230G>T p.W1410C | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759463; called by muse, mutect2
- STARD9 | c.2885G>T p.R962M | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs542925209; called by muse, mutect2, varscan2
- TBX15 | c.1301C>A p.P434H (on ENST00000369429 / NM_001330677.2; = p.P328H on NM_152380.3) | Missense Mutation (SNP) | VAF 69/482 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as COSV99254295; called by muse, mutect2, varscan2
- TGIF1 | c.183+8_183+11del | Splice Region (DEL) | VAF 24/204 reads (12%) | catalogued as rs1286493045; called by pindel, varscan2
- USP54 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528082223; called by muse, mutect2
- YIPF7 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV60656443; called by muse, mutect2
- ZNF318 | c.1840C>G p.R614G | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58931414; called by muse, mutect2, varscan2
- ABCA10 | c.4257-1G>T p.X1419_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- ADAM18 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ADGRL3 | c.4415T>G p.L1472W (on ENST00000506720 / NM_001322402.2; = p.L1361W on NM_015236.6) | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADO | c.129G>C p.M43I | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH1A2 | c.1484T>A p.M495K | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ALG11 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK1 | c.2030A>G p.H677R | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP20 | c.3127G>T p.A1043S | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- BRINP3 | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.676); called by muse, mutect2
- BTBD8 | c.68A>T p.K23M | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CACNA1B | c.3004A>C p.T1002P | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CACNG2 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 101/652 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN6 | c.1003C>G p.H335D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CCDC150 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- CDC6 | c.438_441del p.C146* | Frame Shift Del (DEL) | VAF 33/260 reads (13%) | called by mutect2, pindel, varscan2
- CELF4 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CEP120 | c.2271G>T p.R757S | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CLSTN3 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2
- CNTNAP4 | c.2877G>T p.R959S | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSRP2 | c.507A>T p.G169= | Splice Region (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- CUL3 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYP7A1 | c.1031C>A p.P344Q | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNA2 | c.1108A>T p.S370C | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- DNAH3 | c.10303C>A p.L3435M | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DPY19L2 | c.2185C>A p.P729T | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DROSHA | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DUOX1 | c.3371A>C p.D1124A | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EML6 | c.5077C>A p.L1693M | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC6B | c.2416A>T p.I806F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- FLG2 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 40/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FRMPD1 | c.2269C>G p.H757D | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD4 | c.2764C>A p.L922M | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC5 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPX5 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GTSE1 | c.1750A>T p.R584* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ITGAD | c.3127A>T p.K1043* | Nonsense Mutation (SNP) | VAF 22/225 reads (10%) | called by muse, mutect2, varscan2
- JPH4 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- KCTD12 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2
- KIAA0930 | c.630G>T p.E210D (on ENST00000336156 / NM_001009880.2; = p.E215D on NM_015264.2) | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KIFC1 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KRTAP4-6 | c.197G>A p.C66Y | Missense Mutation (SNP) | VAF 56/429 reads (13%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- LARP1B | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- LIPF | c.888+2T>C p.X296_splice | Splice Site (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- LOXL2 | c.683G>C p.R228P | Missense Mutation (SNP) | VAF 57/490 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LRRC74B | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- MARK1 | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2
- MDC1 | c.1681A>T p.K561* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.224C>G p.T75S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- NMNAT2 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR11H7 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- OR4K1 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR5B12 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5W2 | c.403A>T p.N135Y | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PICK1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 59/408 reads (14%) | called by muse, mutect2, varscan2
- PKP2 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POC1B | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PPM1B | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 100/457 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN7 | c.200C>A p.P67H (on ENST00000495688; = p.P106H on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/333 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RESF1 | c.656G>C p.R219P | Missense Mutation (SNP) | VAF 79/386 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGPD3 | c.255T>C p.R85= | Splice Region (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- RHBG | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.13914-1G>T p.X4638_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- SALL1 | c.3311C>A p.P1104H | Missense Mutation (SNP) | VAF 71/537 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- SBNO2 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SCN5A | c.5605G>T p.D1869Y (on ENST00000333535 / NM_198056.3; = p.D1868Y on NM_000335.5) | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SFI1 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHOC2 | c.1172T>A p.L391* | Nonsense Mutation (SNP) | VAF 44/401 reads (11%) | called by muse, mutect2, varscan2
- SKOR2 | c.1239del p.A414Rfs*82 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- SLC25A47 | c.717C>A p.D239E | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A6 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- STK11 | c.221_222insAGGGCC p.R74_R75insGP | In Frame Ins (INS) | VAF 96/270 reads (36%) | called by mutect2, varscan2*
- SVEP1 | c.7489G>A p.E2497K | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TAS2R40 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TCF20 | c.3692A>T p.K1231I | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TERF2 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TLR4 | c.1172G>T p.C391F (on ENST00000355622 / NM_138554.5; = p.C351F on NM_003266.4) | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TOLLIP | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPM3 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 64/734 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2
- TPO | c.1855G>T p.A619S | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- TRIM35 | c.1409G>C p.R470P | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM55 | c.1529G>T p.G510V (on ENST00000315962 / NM_184085.2; = p.W539C on NM_033058.3) | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- TRIM77 | c.155G>C p.C52S | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRMT13 | c.1216A>G p.R406G | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPV6 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 47/527 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBB8B | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 76/681 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TUT7 | c.2771A>C p.N924T | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBOX5 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UQCRC1 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VRTN | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VSIG8 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 137/425 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC2 | c.2563G>T p.D855Y | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- XYLT1 | c.2639G>T p.S880I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZIC1 | c.1259G>T p.S420I | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZMYND8 | c.277G>T p.V93F (on ENST00000311275 / NM_001363741.2; = p.V113F on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/602 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, varscan2
- ZNF208 | c.2187C>A p.S729R | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, varscan2
- ZNF423 | c.1131C>A p.S377R (on ENST00000563137 / NM_001379286.1; = p.S369R on NM_015069.4) | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF502 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF676 | c.1119A>T p.E373D (on ENST00000650058; = p.E341D on NM_001001411.3) | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- ZNF84 | c.65G>C p.W22S | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ADARB2 | c.618G>A p.P206= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1433243384; called by muse, mutect2, varscan2
- AGBL4 | c.1429C>A p.R477= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- ANKRD17 | c.2200T>C p.L734= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV58225402; called by muse, mutect2
- ARID1B | c.2109G>A p.A703= | Silent (SNP) | VAF 55/354 reads (16%) | catalogued as rs551597753; called by muse, mutect2, varscan2
- BCAT1 | c.375G>A p.V125= | Silent (SNP) | VAF 52/196 reads (27%) | called by muse, varscan2
- CACNA1B | c.3006G>T p.T1002= | Silent (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2
- CD163L1 | c.2061T>C p.D687= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs750496923; called by muse, mutect2, varscan2
- CHCHD2 | c.84A>T p.P28= | Silent (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- CHST1 | c.732C>T p.S244= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV57325273, COSV57325431; called by muse, mutect2, varscan2
- DBX1 | c.726C>T p.R242= | Silent (SNP) | VAF 61/413 reads (15%) | catalogued as COSV57054462; called by muse, mutect2, varscan2
- DMTF1 | c.2265T>C p.D755= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- EPHA8 | c.2970C>G p.T990= | Silent (SNP) | VAF 46/323 reads (14%) | catalogued as COSV51303242; called by muse, mutect2, varscan2
- FLNC | c.579C>A p.A193= | Silent (SNP) | VAF 49/216 reads (23%) | called by muse, mutect2, varscan2
- FOXC2 | c.834G>T p.L278= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2, varscan2
- GABRB3 | c.921C>T p.D307= | Silent (SNP) | VAF 22/424 reads (5%) | catalogued as rs1242193501; called by muse, mutect2
- GAS2L1 | c.384G>T p.V128= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- GPC6 | c.114T>G p.G38= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- IGKV2D-24 | c.22C>T p.L8= | Silent (SNP) | VAF 29/335 reads (9%) | called by muse, mutect2
- JAKMIP1 | c.1461C>A p.R487= | Silent (SNP) | VAF 8/234 reads (3%) | catalogued as rs1044368722; called by muse, mutect2
- JHY | c.507G>A p.T169= | Silent (SNP) | VAF 47/332 reads (14%) | catalogued as rs992412552, COSV56218702; called by muse, mutect2, varscan2
- KCNMA1 | c.3264C>T p.T1088= (on ENST00000286628 / NM_001161352.2; = p.T1030= on NM_002247.4) | Silent (SNP) | VAF 104/565 reads (18%) | called by muse, mutect2, varscan2
- KRT6B | c.444C>A p.L148= | Silent (SNP) | VAF 47/417 reads (11%) | catalogued as COSV52886252; called by muse, mutect2, varscan2
- KSR2 | c.1074G>T p.P358= | Silent (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- LRRTM1 | c.897C>A p.I299= | Silent (SNP) | VAF 58/216 reads (27%) | called by muse, mutect2, varscan2
- MME | c.1377T>A p.T459= | Silent (SNP) | VAF 110/359 reads (31%) | called by muse, mutect2, varscan2
- MSR1 | c.969C>T p.A323= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs1334789677; called by muse, varscan2
- MYH13 | c.3880C>A p.R1294= | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as COSV52822044; called by muse, mutect2, varscan2
- NTM | c.381G>A p.R127= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV66194743; called by muse, varscan2
- NTSR1 | c.930C>A p.I310= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as COSV65138210; called by muse, mutect2, varscan2
- OLFML2A | c.210C>T p.R70= | Silent (SNP) | VAF 99/391 reads (25%) | catalogued as rs374385880; called by muse, mutect2, varscan2
- OTOF | c.5916C>A p.L1972= (on ENST00000272371 / NM_194248.3; = p.L1205= on NM_004802.4) | Silent (SNP) | VAF 60/263 reads (23%) | called by muse, mutect2, varscan2
- OXTR | c.999G>T p.T333= | Silent (SNP) | VAF 27/377 reads (7%) | catalogued as rs189691866, COSV57480847; called by muse, mutect2
- PAQR7 | c.216C>T p.A72= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs376473466; called by muse, mutect2, varscan2
- PKHD1 | c.8415C>A p.V2805= | Silent (SNP) | VAF 86/545 reads (16%) | called by muse, mutect2, varscan2
- PPM1J | c.204C>A p.S68= | Silent (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- PROKR1 | c.261G>T p.L87= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs372842241; called by muse, mutect2, varscan2
- RIPPLY3 | c.447G>A p.G149= | Silent (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- SFMBT2 | c.1626C>T p.Y542= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- SSU72P8 | c.367C>T p.L123= | Silent (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- SYDE1 | c.486C>T p.P162= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs1348976868; called by muse, mutect2, varscan2
- TEX47 | c.480T>C p.D160= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV99787241; called by muse, mutect2, varscan2
- TRAK2 | c.2610T>A p.S870= | Silent (SNP) | VAF 44/525 reads (8%) | called by muse, mutect2
- TTC23L | c.516G>T p.V172= | Silent (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- XPO7 | c.213A>G p.V71= | Silent (SNP) | VAF 29/343 reads (8%) | catalogued as COSV53018048; called by muse, mutect2
- ZNF25 | c.825A>G p.V275= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs182773154; called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824469 C>A | 3'Flank (SNP) | VAF 47/351 reads (13%) | called by muse, mutect2, varscan2
- ACTC1 | c.*12T>C | 3'UTR (SNP) | VAF 28/310 reads (9%) | catalogued as rs753155881; called by muse, mutect2
- AL121827.1 | chr20:63373967 C>G | 3'Flank (SNP) | VAF 66/228 reads (29%) | called by muse, mutect2, varscan2
- BOD1 | c.*55del | 3'UTR (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- C22orf34 | n.869G>T | RNA (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- C22orf34 | n.868G>T | RNA (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- COL27A1 | c.3609+34C>T | Intron (SNP) | VAF 59/242 reads (24%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-60C>G | 5'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs941341241; called by muse, mutect2, varscan2
- DHX40P1 | n.655A>T | RNA (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- DPYSL2 | chr8:26577332 C>T | 5'Flank (SNP) | VAF 6/31 reads (19%) | catalogued as rs1446951955; called by muse, varscan2
- FAM104B | c.-28C>T | 5'UTR (SNP) | VAF 42/78 reads (54%) | catalogued as rs1467675459; called by muse, mutect2, varscan2
- GNG2 | c.-29-36379C>A | Intron (SNP) | VAF 79/240 reads (33%) | called by muse, mutect2, varscan2
- HSPA7 | n.745C>T | RNA (SNP) | VAF 60/438 reads (14%) | called by muse, mutect2, varscan2
- ITSN1 | c.2728-854C>G | Intron (SNP) | VAF 68/421 reads (16%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.1169G>A | RNA (SNP) | VAF 144/391 reads (37%) | catalogued as rs758225635; called by muse, mutect2, varscan2
- KIRREL3 | c.55+5188G>T | Intron (SNP) | VAF 39/346 reads (11%) | called by muse, mutect2, varscan2
- LALBA | c.369-19C>G | Intron (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- LRCOL1 | c.*31G>T | 3'UTR (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- NCAM1 | c.-13C>A | 5'UTR (SNP) | VAF 27/208 reads (13%) | catalogued as rs1555062945; called by muse, mutect2, varscan2
- NF1 | c.60+17G>A | Intron (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2
- NF1 | c.60+19G>A | Intron (SNP) | VAF 32/142 reads (23%) | called by muse, mutect2
- PHACTR1 | c.104-56C>T | Intron (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- RPLP0P2 | n.1626G>T | RNA (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- RPS26P15 | n.313G>C | RNA (SNP) | VAF 35/287 reads (12%) | called by muse, mutect2, varscan2
- STEAP1B | c.706-18811A>G | Intron (SNP) | VAF 76/336 reads (23%) | catalogued as COSV68347973; called by muse, mutect2, varscan2
- TRADD | c.151+373G>A | Intron (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- USF2 | c.951+24T>A | Intron (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- XIST | n.11295A>G | RNA (SNP) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- ZNF252P | n.1399C>G | RNA (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
